Surgical pathology report (de-identified scan), TCGA case TCGA-G2-AA3D, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site MD Anderson, specimen TCGA-G2-AA3D-01A (Primary Tumor).

ICD-O-3
Carcinoma, urothelial NOS
8120/3
Site: Bladder NOS
C67.9
JW 11/17/14

DIAGNOSIS

(A) BLADDER TUMOR:

UROTHELIAL CARCINOMA, HIGH-GRADE, INVASIVE INTO MUSCULARIS PROPRIA.

LYMPHOVASCULAR INVASION PRESENT.

Fragments of bladder wall including muscularis propria show chronic inflammation and granulation tissue consistent with previous biopsy site.

GROSS DESCRIPTION

(A) BLADDER TUMOR – Received are multiple fragments of tan-pink to gray-white soft tissue aggregating to 2.2 x 1.1 x 0.5 cm. The specimen is submitted entirely in A.

CLINICAL HISTORY

Bladder CA.

Source: NCI Genomic Data Commons file c4c352d4-813b-4415-a010-2153a36f4105 (TCGA-G2-AA3D.F4A8627A-5551-4E1D-A49E-370FD0F39D02.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).